Somatic mutation profile of tumor specimen TCGA-RW-A686-06A (aliquot TCGA-RW-A686-06A-11D-A35D-08) from TCGA case TCGA-RW-A686, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 62.2 years (22,718 days).
Specimen TCGA-RW-A686-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a64c6172-7d36-497c-8917-ed95556b69d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A686-10A (Blood Derived Normal), aliquot TCGA-RW-A686-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95a6bb6e-4e46-430c-84b8-8cb08013f215

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAS1 | c.75C>T p.D25= | Splice Region (SNP) | VAF 12/64 reads (19%) | catalogued as rs1326891118, COSV65084835; called by muse, mutect2, varscan2
- ITGB1 | c.524_526del p.R175del | In Frame Del (DEL) | VAF 39/136 reads (29%) | catalogued as rs751489253; called by pindel, varscan2
- MYH15 | c.3567C>A p.D1189E | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as rs1437952234; called by muse, mutect2
- OTOP1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56395464; called by muse, mutect2
- ABCA12 | c.817T>A p.F273I | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ABCD1 | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.084); called by muse, mutect2
- APOL2 | c.392C>G p.T131S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GLB1L3 | c.1621G>T p.G541C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- GATAD2B | c.207C>T p.G69= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as COSV64083934; called by muse, mutect2
- NCAPD3 | c.3786G>A p.Q1262= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs1425093919; called by muse, mutect2, varscan2
- PRKD1 | c.2458C>T p.L820= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs1212823056; called by muse, mutect2, varscan2
- SPTB | c.5703C>T p.D1901= | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
